CCDI case PBCFHT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/022d33f1-8484-43a0-8e47-3996853b5bbc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Small cell sarcoma: ICD-O-3 morphology code: 8803/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 14.4 years (5,253 days).

Biospecimens (2 samples)
- Sample 0DQS05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQS0M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
